Gene-level copy-number profile of tumor specimen ALCH-B4E8-TTP1-A from ALCHEMIST case ALCH-B4E8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.3 years (26,029 days).
Specimen ALCH-B4E8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a74df6b-dc34-4d42-bd4d-01d2558642d9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4E8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,255 have no estimate.
https://portal.gdc.cancer.gov/files/c77a4854-a733-428d-8674-9670a58c741a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 904; copy number 2: 55,493; copy number 3: 1,694; copy number 4: 198; copy number 5: 19; copy number 6: 7; copy number 8: 5; copy number 9: 2; copy number 10: 2; copy number 11: 1; copy number 14: 15; copy number 15: 1; copy number 23: 2.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–2): AL139423.1.
- chr1:226,127,178–226,127,346, 1 gene: AL512343.1.
- chr7:6,637,318–6,658,279, 1 gene: ZNF316.
- chr7:129,756,266–129,785,185, 5 genes (within-gene range 0–2): RNA5SP244, MIR182, MIR96, MIR183, AC084864.1.
- chr9:105,849,710–105,851,425, 1 gene: SLC25A6P5.
- chr10:49,734,641–49,762,379, 1 gene: OGDHL.
- chr15:75,674,322–75,738,623, 5 genes (within-gene range 0–2): CSPG4, AC105020.4, AC105020.1, ODF3L1, DNM1P35.
- chr15:89,201,091–89,221,614, 2 genes (within-gene range 0–2): AC124068.1, RLBP1.
- chr17:21,376,357–21,419,870, 1 gene: KCNJ12.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr18:79,470,120–79,470,940, 1 gene (within-gene range 0–2): AC018445.1.
- chr19:55,476,617–55,487,568, 2 genes: ZNF628, NAT14.
- chr22:18,794,414–18,794,804, 1 gene (within-gene range 0–4): AC008132.2.
- chr22:46,541,495–46,548,196, 1 gene: AL021392.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 54 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–110,138, 7 genes, copy number 5–9: WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1.
- chr16:33,094,204–33,570,935, 19 genes, copy number 6–14 (within-gene range 2–14): HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr20:62,841,005–63,240,495, 21 genes, copy number 5–6 (within-gene range 3–6): TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056, HAR1B, AL096828.4, HAR1A, AL096828.2, AL096828.1, MIR124-3, YTHDF1, AL096828.3, BIRC7, MIR3196.
- chr22:18,623,339–18,757,906, 5 genes, copy number 8–23: SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.
- chr22:18,846,811–18,861,049, 2 genes, copy number 10: AC008132.1, BCRP7.

Autosomal genes at a single copy (total copy number 1): 821. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
